TCGA case TCGA-4R-AA8I — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Duke University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/91a0c8cd-4f23-4569-8e5c-e5442f7af530

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Dead; Days to death: 262 days.

Diagnoses (4)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 66.5 years (24,279 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 262 days; Child pugh classification: A; Ishak fibrosis score: 6 - Established Cirrhosis.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: Yes; Vascular invasion type: Micro.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Basal cell carcinoma, NOS: ICD-O-3 morphology code: 8090/3; Tissue or organ of origin: External ear; Laterality: Left; Classification of tumor: Prior primary; Age at diagnosis: 61.1 years (22,324 days); Days to diagnosis: -1,955 days (-5.4 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,955 days (-5.4 years); Treatment anatomic sites: Skin.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 66.9 years (24,437 days); Days to diagnosis: 158 days; Prior treatment: Yes.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
4. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 67.1 years (24,526 days); Days to diagnosis: 247 days; Prior treatment: Yes.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (5 entries)
- Day 158 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Liver; Days to recurrence: 158 days.
- Days to follow up: 216 days; Disease response: With Tumor.
- Day 247 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Liver; Days to recurrence: 247 days.
- Days to follow up: 262 days; Disease response: With Tumor.
- ECOG performance status: 1.

Molecular and laboratory tests
- Platelets 96 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].
- Total Bilirubin 1.2 mg/dL [Blood test normal range lower: 0.4; Blood test normal range upper: 1.5].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1.1 [Blood test normal range lower: 0.8; Blood test normal range upper: 1.1].
- Alpha Fetoprotein 5 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 9].
- Albumin 3.8 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 4.8].
- Creatinine 0.7 mg/dL [Blood test normal range lower: 0.6; Blood test normal range upper: 1.3].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 103 kg; Height: 171 cm; BMI: 35.2.
- Timepoint category: Prior to Diagnosis; Risk factors: Nonalcoholic Fatty Liver Disease; Viral hepatitis serology tests: Hepatitis B Surface Antigen / Hepatitis C Antibody.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-4R-AA8I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 210 mg.
  Slide TCGA-4R-AA8I-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-4R-AA8I-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-4R-AA8I-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Single.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis  C Antibody; Viral hepatitis serology: Hepatitis B Surface Antigen.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Ear; Other malignancy histological type: Basal Cell Carcinoma, nodular pattern.
- Other malignancy form, Surgery: Other malignancy surgery type: Skin shave biopsy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 262 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 262 days; disease-free interval: event (new tumor event after initially disease-free), 158 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 158 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-4R-AA8I-01A-11D-A381-01): tumor purity 0.85, ploidy 1.93, whole-genome doublings 0.
